Somatic mutation profile of cancer-model specimen HCM-CSHL-0093-C25-85A (3D Organoid; aliquot HCM-CSHL-0093-C25-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0093-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.0 years (25,941 days).
Specimen HCM-CSHL-0093-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dccd871c-193c-45e7-88ed-3a2de59f021f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0093-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0093-C25-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/def59c4c-def8-4efa-9f90-91dfb343dbcd

The open-access MAF lists 129 somatic variants for this specimen: 52 protein-altering or splice-affecting, 60 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 60, Missense Mutation 41, Intron 9, Nonsense Mutation 4, Frame Shift Ins 3, 5'UTR 3, Splice Region 2, Frame Shift Del 2, 5'Flank 2, 3'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 186/376 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 156/156 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BHLHE22 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.99); catalogued as rs1563530664, COSV58862029; called by muse, mutect2, varscan2
- CPVL | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 246/391 reads (63%) | catalogued as rs1164326160, COSV55309812; called by muse, mutect2, varscan2
- CUX2 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 292/293 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409428904; called by muse, mutect2, varscan2
- ELFN1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 481/734 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366805556; called by muse, mutect2, varscan2
- GABRQ | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as rs781850425, COSV64781257, COSV64781718; called by muse, mutect2
- GLB1L | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168507273; called by muse, mutect2, varscan2
- HDAC6 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 147/279 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs781807565; called by muse, mutect2, varscan2
- KCNK9 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 227/682 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57280170; called by muse, mutect2, varscan2
- KDM6B | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV54677683; called by muse, mutect2
- KIAA1549L | c.4813G>T p.V1605L (on ENST00000321505; = p.V1902L on NM_012194.3) | Missense Mutation (SNP) | VAF 169/327 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs1174469662; called by muse, mutect2, varscan2
- KIF18B | c.2036G>T p.R679M (on ENST00000593135 / NM_001265577.2; = p.R691M on NM_001264573.2) | Missense Mutation (SNP) | VAF 115/226 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV100192027; called by muse, mutect2, varscan2
- LAMA1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 210/592 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as rs758995991; called by muse, mutect2, varscan2
- MAEL | c.132G>A p.A44= | Splice Region (SNP) | VAF 80/166 reads (48%) | catalogued as rs1296702154; called by muse, mutect2
- MARK2 | c.1444C>T p.R482* (on ENST00000402010 / NM_001039469.2; = p.R481* on NM_004954.5) | Nonsense Mutation (SNP) | VAF 140/339 reads (41%) | catalogued as rs1388342422, COSV59280212, COSV59285981; called by muse, mutect2, varscan2
- MYO16 | c.4412C>T p.P1471L | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs1239669258; called by muse, mutect2, varscan2
- NAPSA | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 258/537 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs536389281; called by muse, mutect2, varscan2
- NR1D1 | c.1739T>C p.L580S | Missense Mutation (SNP) | VAF 41/604 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52840542; called by muse, mutect2
- OBSCN | c.14309G>A p.R4770H | Missense Mutation (SNP) | VAF 204/384 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs376545906, COSV52810429; called by muse, mutect2, varscan2
- OCSTAMP | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 282/592 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV54098386; called by muse, mutect2, varscan2
- OGDH | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 323/484 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56057029; called by muse, mutect2, varscan2
- OR4A15 | c.107C>G p.T36R | Missense Mutation (SNP) | VAF 119/230 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV59033672; called by muse, mutect2, varscan2
- PFKFB1 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 108/263 reads (41%) | PolyPhen possibly damaging (0.564); catalogued as rs201730176, COSV99436886; called by muse, mutect2, varscan2
- PID1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.791); catalogued as rs771130057; called by muse, mutect2, varscan2
- PRDM6 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 213/383 reads (56%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.641); catalogued as rs1198720809; called by muse, mutect2, varscan2
- REXO5 | c.138G>A p.K46= | Splice Region (SNP) | VAF 82/179 reads (46%) | catalogued as rs1449666793; called by muse, mutect2, varscan2
- RGS7 | c.1295G>C p.S432T | Missense Mutation (SNP) | VAF 170/366 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV58552477; called by muse, mutect2, varscan2
- SFMBT2 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 133/341 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs138486122, COSV62809446; called by muse, mutect2, varscan2
- SLC25A11 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201382412, COSV52591096; called by muse, mutect2, varscan2
- SLC8A2 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52639417; called by muse, mutect2, varscan2
- TEX13C | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 360/806 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.035); catalogued as rs1251413087; called by muse, mutect2, varscan2
- TUBA3D | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.4); catalogued as rs772833046, COSV58311934; called by muse, mutect2, varscan2
- ACVR2A | c.40dup p.I14Nfs*11 | Frame Shift Ins (INS) | VAF 149/366 reads (41%) | called by mutect2, pindel, varscan2
- ACVR2A | c.409del p.Y137Tfs*13 | Frame Shift Del (DEL) | VAF 106/244 reads (43%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARID1A | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- ATP1B1 | c.57dup p.E20Rfs*15 | Frame Shift Ins (INS) | VAF 105/286 reads (37%) | called by mutect2, pindel, varscan2
- ENOX2 | c.1089C>A p.C363* (on ENST00000338144 / NM_001382520.1; = p.C334* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 117/240 reads (49%) | called by muse, mutect2, varscan2
- GGTLC2 | c.377A>C p.D126A | Missense Mutation (SNP) | VAF 345/391 reads (88%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNE | c.409A>T p.I137F (on ENST00000396594 / NM_001128227.3; = p.I106F on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, varscan2
- INTS4 | c.651del p.A218Pfs*10 | Frame Shift Del (DEL) | VAF 40/119 reads (34%) | called by mutect2, pindel, varscan2
- KRTAP2-3 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 101/275 reads (37%) | called by muse, mutect2, varscan2
- MTMR3 | c.3268T>G p.L1090V | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- OPA3 | c.377_378insTT p.G127Wfs*62 | Frame Shift Ins (INS) | VAF 201/555 reads (36%) | called by mutect2, pindel, varscan2
- OR4F6 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PPP1R37 | c.1529A>G p.D510G | Missense Mutation (SNP) | VAF 110/221 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB39B | c.323A>T p.K108I | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- STARD7 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 262/548 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- TGM1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 284/562 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- TRIL | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- VEGFC | c.1113A>C p.L371F | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- ADCY8 | c.1260T>C p.V420= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- ADGRB2 | c.864A>G p.K288= | Silent (SNP) | VAF 28/1000 reads (3%) | called by muse, mutect2
- AEBP2 | c.1041T>C p.R347= | Silent (SNP) | VAF 15/316 reads (5%) | catalogued as COSV56864217; called by muse, mutect2
- AGAP1 | c.138C>T p.I46= | Silent (SNP) | VAF 22/552 reads (4%) | catalogued as rs1233050699; called by muse, mutect2
- AMD1 | c.261G>A p.L87= | Silent (SNP) | VAF 23/314 reads (7%) | catalogued as rs1284561715, COSV64386891; called by muse, mutect2
- AMD1 | c.402A>C p.I134= | Silent (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- BIRC6 | c.4893A>G p.L1631= | Silent (SNP) | VAF 13/267 reads (5%) | catalogued as COSV70195417, COSV70207251; called by muse, mutect2
- BRPF1 | c.2736C>A p.P912= | Silent (SNP) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- C12orf66 | c.192C>T p.A64= | Silent (SNP) | VAF 18/442 reads (4%) | catalogued as COSV61323800; called by muse, mutect2
- CABIN1 | c.4011C>T p.L1337= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- CAPZA1 | c.828C>T p.S276= | Silent (SNP) | VAF 21/320 reads (7%) | called by muse, mutect2
- CATSPERG | c.1995G>A p.P665= | Silent (SNP) | VAF 273/568 reads (48%) | called by muse, mutect2, varscan2
- CKS2 | c.159C>A p.G53= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- CLK3 | c.870T>C p.G290= (on ENST00000395066 / NM_001130028.1; = p.G142= on NM_003992.4) | Silent (SNP) | VAF 15/278 reads (5%) | catalogued as rs1323690218, COSV61411668; called by muse, mutect2
- FAM120A | c.42C>T p.C14= | Silent (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- FAM222B | c.891C>T p.P297= | Silent (SNP) | VAF 14/433 reads (3%) | catalogued as COSV57927626; called by muse, mutect2
- FBXO41 | c.123C>T p.L41= | Silent (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- FGF8 | c.219A>G p.Q73= (on ENST00000344255 / NM_033164.4; = p.Q55= on NM_006119.6) | Silent (SNP) | VAF 25/526 reads (5%) | catalogued as rs1564632353; called by muse, mutect2
- FOXC1 | c.462G>C p.L154= | Silent (SNP) | VAF 36/744 reads (5%) | catalogued as COSV66515595; called by muse, mutect2
- GPR27 | c.645G>A p.R215= | Silent (SNP) | VAF 24/294 reads (8%) | catalogued as rs1325267630; called by muse, mutect2
- GRIK5 | c.1824G>A p.S608= | Silent (SNP) | VAF 172/182 reads (95%) | catalogued as rs747358547; called by muse, varscan2
- H2AW | c.345A>G p.V115= | Silent (SNP) | VAF 155/678 reads (23%) | catalogued as rs761793820, COSV64209514; called by muse, mutect2
- HEATR3 | c.1830T>C p.V610= | Silent (SNP) | VAF 116/286 reads (41%) | called by muse, mutect2, varscan2
- HIC1 | c.165C>T p.N55= (on ENST00000322941 / NM_001098202.1; = p.N36= on NM_006497.4) | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs1166675422, COSV53964457; called by muse, varscan2
- HIC1 | c.246C>A p.L82= (on ENST00000322941 / NM_001098202.1; = p.L63= on NM_006497.4) | Silent (SNP) | VAF 22/223 reads (10%) | catalogued as COSV53964464; called by muse, mutect2
- HNRNPAB | c.864T>G p.P288= | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as COSV57422728; called by muse, mutect2
- HOXB5 | c.159C>T p.D53= | Silent (SNP) | VAF 15/362 reads (4%) | catalogued as COSV53312084; called by muse, mutect2
- ILF3 | c.579C>T p.D193= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV51553946; called by muse, mutect2
- INA | c.276C>T p.T92= | Silent (SNP) | VAF 13/286 reads (5%) | catalogued as rs1300502901; called by muse, mutect2
- IRX2 | c.261C>T p.Y87= | Silent (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- KCNH2 | c.45G>C p.L15= | Silent (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- KDM5C | c.2178C>T p.D726= | Silent (SNP) | VAF 298/589 reads (51%) | catalogued as rs375715339, COSV64764832; called by muse, mutect2, varscan2
- KDM6B | c.1137C>T p.T379= | Silent (SNP) | VAF 22/330 reads (7%) | catalogued as COSV54677694, COSV54687111; called by muse, mutect2
- KHDC4 | c.1125A>G p.Q375= | Silent (SNP) | VAF 16/406 reads (4%) | catalogued as COSV64164468; called by muse, mutect2
- MLLT3 | c.627A>G p.K209= | Silent (SNP) | VAF 18/303 reads (6%) | catalogued as COSV63494445; called by muse, mutect2
- MTA1 | c.1245T>C p.R415= | Silent (SNP) | VAF 20/460 reads (4%) | catalogued as COSV58755542; called by muse, mutect2
- MTTP | c.186C>T p.N62= | Silent (SNP) | VAF 117/223 reads (52%) | catalogued as rs776338005; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH11 | c.1458C>G p.L486= | Silent (SNP) | VAF 38/984 reads (4%) | called by muse, mutect2
- PATZ1 | c.1590G>A p.E530= | Silent (SNP) | VAF 14/273 reads (5%) | catalogued as COSV56743083; called by muse, mutect2
- PRDM12 | c.891C>T p.R297= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs1485226225, COSV53390720; called by muse, mutect2, varscan2
- PSMA5 | c.522A>T p.S174= | Silent (SNP) | VAF 36/452 reads (8%) | called by muse, mutect2
- RAN | c.354G>A p.V118= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV54562099; called by muse, mutect2
- RNF11 | c.96G>A p.P32= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV54377257; called by muse, mutect2
- RYR2 | c.4761C>T p.H1587= | Silent (SNP) | VAF 136/277 reads (49%) | catalogued as rs369612535; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD1 | c.105C>T p.I35= | Silent (SNP) | VAF 10/183 reads (5%) | catalogued as rs1426383241, COSV54115669; called by muse, mutect2
- SCN7A | c.373C>T p.L125= | Silent (SNP) | VAF 74/162 reads (46%) | called by muse, mutect2, varscan2
- SFRP1 | c.264G>A p.A88= | Silent (SNP) | VAF 31/257 reads (12%) | catalogued as COSV55174722; called by muse, varscan2
- SLC16A3 | c.315G>A p.A105= | Silent (SNP) | VAF 130/273 reads (48%) | catalogued as rs775658584; called by muse, mutect2, varscan2
- SMARCC2 | c.3507A>G p.Q1169= | Silent (SNP) | VAF 21/641 reads (3%) | catalogued as COSV53237190; called by muse, mutect2
- SMARCD3 | c.1233C>T p.S411= (on ENST00000262188 / NM_001003801.2; = p.S398= on NM_003078.4) | Silent (SNP) | VAF 23/489 reads (5%) | called by muse, mutect2
- SMO | c.2307T>C p.I769= | Silent (SNP) | VAF 119/226 reads (53%) | called by muse, mutect2, varscan2
- STK39 | c.225T>A p.A75= | Silent (SNP) | VAF 108/206 reads (52%) | called by muse, mutect2, varscan2
- STRBP | c.732A>G p.E244= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as rs1283035909; called by muse, mutect2
- TOGARAM2 | c.2905C>T p.L969= | Silent (SNP) | VAF 292/588 reads (50%) | called by muse, mutect2, varscan2
- TSNARE1 | c.390G>T p.P130= | Silent (SNP) | VAF 100/159 reads (63%) | catalogued as rs774560278, COSV100210614, COSV56170522; called by muse, mutect2, varscan2
- UBAP2L | c.9A>G p.T3= | Silent (SNP) | VAF 20/375 reads (5%) | called by muse, mutect2
- UBAP2L | c.2673T>C p.H891= | Silent (SNP) | VAF 20/530 reads (4%) | catalogued as COSV55174714; called by muse, mutect2
- UNC79 | c.4929C>T p.V1643= (on ENST00000393151 / NM_001346218.2; = p.V1466= on NM_020818.5) | Silent (SNP) | VAF 134/298 reads (45%) | catalogued as rs1163629494; called by muse, mutect2, varscan2
- ZDHHC21 | c.754A>C p.R252= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV66612004; called by muse, varscan2
- ZNF311 | c.1276C>A p.R426= | Silent (SNP) | VAF 258/562 reads (46%) | catalogued as rs752812603, COSV65852967; called by muse, mutect2, varscan2
- COL11A1 | c.898-227A>G | Intron (SNP) | VAF 210/407 reads (52%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892856 C>G | 5'Flank (SNP) | VAF 11/160 reads (7%) | catalogued as COSV61482292; called by muse, mutect2
- DMAP1 | c.394-40C>T | Intron (SNP) | VAF 209/745 reads (28%) | called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2793T>C | Intron (SNP) | VAF 6/9 reads (67%) | called by muse, varscan2
- ETS2 | c.-120T>G | 5'UTR (SNP) | VAF 110/313 reads (35%) | called by muse, mutect2, varscan2
- GLA | c.1000-37C>T | Intron (SNP) | VAF 96/216 reads (44%) | catalogued as rs782099278; called by muse, mutect2, varscan2
- HOXC9 | c.-7C>T | 5'UTR (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- MAPK12 | c.1024+22C>T | Intron (SNP) | VAF 187/187 reads (100%) | catalogued as rs199917786; called by muse, mutect2, varscan2
- MIR212 | n.66C>T | RNA (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- NANOS3 | chr19:13874760 G>A | 5'Flank (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- PPP2R2B | c.-59A>T | 5'UTR (SNP) | VAF 34/408 reads (8%) | catalogued as COSV60768468; called by muse, mutect2
- RPLP1 | chr15:69458687 del C | 3'Flank (DEL) | VAF 52/125 reads (42%) | called by mutect2, pindel, varscan2
- SEMA5A | c.271-27607G>C | Intron (SNP) | VAF 118/350 reads (34%) | called by muse, mutect2
- SETD5 | c.178-157A>G | Intron (SNP) | VAF 11/166 reads (7%) | catalogued as COSV56712180; called by muse, mutect2
- SRPK2 | c.1882+441C>T | Intron (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- TTC6 | c.357+1576A>C | Intron (SNP) | VAF 103/194 reads (53%) | called by muse, mutect2, varscan2
- ZNF827 | c.*3T>G | 3'UTR (SNP) | VAF 11/263 reads (4%) | catalogued as COSV65230716; called by muse, mutect2
